Somatic mutation profile of tumor specimen TCGA-E1-A7YO-01A (aliquot TCGA-E1-A7YO-01A-11D-A34A-08) from TCGA case TCGA-E1-A7YO, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 45.9 years (16,770 days).
Specimen TCGA-E1-A7YO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2213dbc8-9288-4b79-9d63-fc303ad42d77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YO-10A (Blood Derived Normal), aliquot TCGA-E1-A7YO-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69a5bd2c-c271-4f34-b37a-dc17d6c7c651

The open-access MAF lists 37 somatic variants for this specimen: 31 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 24, Silent 6, Splice Site 2, Frame Shift Del 2, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 41/91 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- KIF26B | c.6071G>A p.R2024H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199933797, COSV63638897; called by muse, mutect2, varscan2
- ANKAR | c.967A>T p.I323F | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV99854801; called by muse, mutect2, varscan2
- APOBEC3B | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs771690446, COSV100213881; called by muse, mutect2, varscan2
- ARHGAP35 | c.236T>G p.V79G | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV101351875; called by muse, mutect2, varscan2
- ARL6IP6 | c.377C>G p.A126G | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100424149; called by muse, mutect2
- ATP1B4 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as COSV99486621; called by muse, mutect2
- AVPR1A | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100146928; called by muse, mutect2, varscan2
- CEP350 | c.195G>C p.K65N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.415); catalogued as COSV100658366; called by muse, mutect2, varscan2
- CIC | c.3347dup p.S1117Kfs*34 | Frame Shift Ins (INS) | VAF 8/43 reads (19%) | catalogued as rs761345552; called by mutect2, varscan2
- CLSPN | c.356T>C p.L119S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs776299439, COSV99231708; called by muse, mutect2, varscan2
- CYP11A1 | c.1434+1G>A p.X478_splice | Splice Site (SNP) | VAF 26/58 reads (45%) | catalogued as COSV99166283; called by muse, mutect2, varscan2
- D2HGDH | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs901746208, COSV100345045; called by muse, mutect2, varscan2
- DNASE2 | c.125G>C p.G42A | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.215); catalogued as COSV99322330, COSV99322530; called by muse, mutect2, varscan2
- FUBP1 | c.637-1G>A p.X213_splice | Splice Site (SNP) | VAF 59/74 reads (80%) | catalogued as COSV53931715; called by muse, mutect2, varscan2
- NEK10 | c.2840C>T p.T947I | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99835765; called by muse, mutect2, varscan2
- NKX2-1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100702063; called by muse, mutect2, varscan2
- PRMT5 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.896); catalogued as COSV99363227; called by muse, mutect2, varscan2
- PSG9 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as rs754202086, COSV52483752; called by muse, mutect2, varscan2
- SLC38A1 | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.345); catalogued as COSV101284303; called by muse, mutect2, varscan2
- SMC1A | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100447585; called by muse, mutect2, varscan2
- SPIN2A | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100888074; called by muse, mutect2, varscan2
- SPOUT1 | c.388A>C p.T130P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.131); catalogued as COSV100778283; called by muse, mutect2, varscan2
- TCHHL1 | c.650del p.K217Rfs*31 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs754603014, COSV64287552; called by mutect2, pindel, varscan2
- TMEM45B | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.304); catalogued as COSV99859600; called by muse, mutect2, varscan2
- TTN | c.55336G>A p.G18446S (on ENST00000591111; = p.G11022S on NM_003319.4) | Missense Mutation (SNP) | VAF 74/188 reads (39%) | PolyPhen probably damaging (0.999); catalogued as rs761836336, COSV100634371; called by muse, mutect2, varscan2
- ZCRB1 | c.221A>C p.K74T | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.048); catalogued as COSV99861371; called by muse, mutect2
- ABCA13 | c.8311del p.L2771Ffs*2 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- CIC | c.1904dup p.N636Kfs*54 | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- IGHV3-20 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF84 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ABCA7 | c.2418C>T p.G806= | Silent (SNP) | VAF 49/131 reads (37%) | catalogued as rs567147407, COSV99566792; called by muse, mutect2, varscan2
- CENPL | c.237C>T p.P79= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs769813360; called by muse, mutect2, varscan2
- LTK | c.1002C>T p.G334= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs542040990, COSV55489027; called by muse, mutect2, varscan2
- TRIM75P | c.1095T>C p.I365= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV72295842; called by muse, mutect2
- VSIR | c.333C>T p.H111= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as rs749448731, COSV99824367; called by muse, mutect2, varscan2
- ZNF131 | c.390T>C p.A130= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as COSV100185789; called by muse, varscan2
